Somatic mutation profile of tumor specimen BA2329D (aliquot aq-BA2329D) from BEATAML1.0 case 2186, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.8 years (22,579 days).
Specimen BA2329D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d66dc04c-6ee7-40f3-b1dd-5e2c3a88f54f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2099D (Solid Tissue Normal), aliquot aq-BA2099D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fa77953-bd7d-4d99-93ff-dbc6a5c7f57d

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- SLC4A1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 90/228 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs186542577; called by muse, mutect2, varscan2
- EIF4G3 | c.1578A>G p.E526= | Silent (SNP) | VAF 50/105 reads (48%) | called by muse, mutect2, varscan2
- EFR3B | c.2142+31C>A | Intron (SNP) | VAF 5/89 reads (6%) | catalogued as COSV99271231; called by muse, mutect2
